Somatic mutation profile of tumor specimen HCM-CSHL-0057-C18-01B (aliquot HCM-CSHL-0057-C18-01B-01D-A786-36) from HCMI case HCM-CSHL-0057-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GB; Age at diagnosis: 68.4 years (24,973 days).
Specimen HCM-CSHL-0057-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6796498f-38bf-4304-8f84-fbc04feddaee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0057-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0057-C18-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb39fee7-c32d-4786-9aad-c77097216000

The open-access MAF lists 89 somatic variants for this specimen: 57 protein-altering or splice-affecting, 24 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 24, Nonsense Mutation 4, 3'UTR 2, Splice Region 2, RNA 2, Frame Shift Del 2, Intron 2, 5'Flank 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 123/161 reads (76%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS6 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758167428; called by muse, mutect2, varscan2
- ADGRB1 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 97/274 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774842173; called by muse, mutect2, varscan2
- ANKRD53 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 87/153 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.221); catalogued as rs1553423084; called by muse, mutect2, varscan2
- CBY2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 54/341 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs764889227, COSV100137847; called by muse, mutect2, varscan2
- CDH23 | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 113/280 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs749805386, COSV56472692; called by muse, mutect2, varscan2
- DCAF12L2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 120/146 reads (82%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1229366218, COSV63580270, COSV63581169; called by muse, mutect2, varscan2
- GATA3 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 104/295 reads (35%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.8); catalogued as rs767671768, COSV60519223; called by muse, mutect2, varscan2
- GSDMC | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs369692449, COSV52695873, COSV52696298; called by muse, mutect2, varscan2
- HIP1 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 92/502 reads (18%) | catalogued as rs782392081; called by muse, mutect2, varscan2
- KRT9 | c.1441A>T p.S481C | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.053); catalogued as COSV55852320; called by muse, mutect2, varscan2
- LRRTM4 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 71/361 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs1289836030, COSV69138812, COSV69141526; called by muse, mutect2, varscan2
- MPP4 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370307780; called by muse, mutect2, varscan2
- MYT1 | c.3308C>T p.P1103L | Missense Mutation (SNP) | VAF 164/334 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs377470537; called by muse, mutect2, varscan2
- NRK | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV54590098, COSV99687923; called by muse, mutect2, varscan2
- NRXN1 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 182/352 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372823663; called by muse, mutect2, varscan2
- OBSCN | c.9490C>T p.R3164C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs369458693, COSV99486553; called by muse, mutect2, varscan2
- PKHD1 | c.4687G>A p.G1563S | Missense Mutation (SNP) | VAF 271/560 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.183); catalogued as COSV100583349; called by muse, mutect2, varscan2
- PKHD1L1 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV101005680; called by muse, mutect2, varscan2
- PLXNA2 | c.5632C>T p.R1878W | Missense Mutation (SNP) | VAF 90/253 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs141651654; called by muse, mutect2, varscan2
- PRDM9 | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 180/291 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs775142209, COSV57014387; called by muse, mutect2, varscan2
- RABL6 | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1437590053; called by muse, mutect2, varscan2
- RFXANK | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 157/533 reads (29%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.868); catalogued as rs753776724; called by muse, mutect2, varscan2
- RNASEL | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 196/554 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs746370635, COSV100842660; called by muse, mutect2, varscan2
- SCUBE1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as rs563690047, COSV62611479; called by muse, mutect2, varscan2
- SLC26A4 | c.1002G>T p.G334= | Splice Region (SNP) | VAF 38/240 reads (16%) | catalogued as COSV55916993; called by muse, mutect2, varscan2
- SPTBN2 | c.4885A>C p.K1629Q | Missense Mutation (SNP) | VAF 152/301 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs990233587; called by muse, mutect2, varscan2
- STK3 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 80/179 reads (45%) | catalogued as rs763527585, COSV101372443; called by muse, varscan2
- TFAP2D | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 41/685 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as rs143299031; called by muse, mutect2
- TIAM1 | c.3654C>T p.D1218= | Splice Region (SNP) | VAF 25/73 reads (34%) | catalogued as rs375189386; called by muse, mutect2, varscan2
- TMEM221 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs866472518; called by muse, mutect2, varscan2
- VPREB1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 121/330 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs372350881; called by muse, mutect2, varscan2
- ZNF536 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV62819896, COSV62831299; called by muse, mutect2, varscan2
- ZSCAN1 | c.600G>T p.L200F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.104); catalogued as rs1246147132; called by muse, mutect2
- APOB | c.8437C>T p.Q2813* | Nonsense Mutation (SNP) | VAF 49/216 reads (23%) | called by muse, mutect2, varscan2
- CCDC166 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 152/243 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CNNM1 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DPYSL2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- EDIL3 | c.296C>A p.T99K | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2
- EPB41L5 | c.665A>G p.N222S | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.3626A>C p.K1209T | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- FOXD4L5 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 108/805 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GPR149 | c.1442C>A p.A481D | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- HHLA2 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated, low confidence (0.64); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- IGF2BP1 | c.1349A>T p.K450I | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- IGKV1-12 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 177/793 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MMRN1 | c.2656G>T p.V886F | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NCKAP1L | c.1700C>A p.A567D | Missense Mutation (SNP) | VAF 92/501 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NEB | c.4601A>G p.N1534S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- OVCH2 | c.1083T>A p.D361E | Missense Mutation (SNP) | VAF 67/296 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PSD | c.785del p.P262Hfs*32 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- SPTBN5 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TEX10 | c.2417del p.Y806Ffs*6 | Frame Shift Del (DEL) | VAF 31/113 reads (27%) | called by mutect2, pindel, varscan2
- TP53 | c.757dup p.T253Nfs*11 | Frame Shift Ins (INS) | VAF 188/333 reads (56%) | called by mutect2, pindel, varscan2
- UMODL1 | c.2621C>T p.A874V (on ENST00000408910 / NM_001004416.2; = p.A1002V on NM_173568.3) | Missense Mutation (SNP) | VAF 91/277 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ZHX1 | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 77/352 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZNF347 | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- AC011462.1 | c.897G>A p.R299= | Silent (SNP) | VAF 115/494 reads (23%) | catalogued as COSV99524413; called by muse, mutect2, varscan2
- BICDL1 | c.714C>T p.N238= | Silent (SNP) | VAF 98/371 reads (26%) | called by muse, mutect2, varscan2
- BNC2 | c.1299G>A p.G433= | Silent (SNP) | VAF 96/250 reads (38%) | called by muse, mutect2, varscan2
- CCDC168 | c.5187G>A p.P1729= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as rs780744858, COSV70554779; called by muse, mutect2, varscan2
- CLTC | c.54G>A p.L18= | Silent (SNP) | VAF 93/241 reads (39%) | catalogued as COSV52253967; called by muse, mutect2, varscan2
- DNHD1 | c.10041C>T p.D3347= | Silent (SNP) | VAF 74/298 reads (25%) | catalogued as rs1415822771; called by muse, mutect2, varscan2
- FGD5 | c.1410G>T p.L470= | Silent (SNP) | VAF 66/184 reads (36%) | called by muse, mutect2, varscan2
- FREM1 | c.6231G>A p.A2077= | Silent (SNP) | VAF 51/122 reads (42%) | catalogued as rs148735553; called by muse, mutect2, varscan2
- ICE1 | c.1980T>A p.T660= | Silent (SNP) | VAF 50/88 reads (57%) | called by muse, varscan2
- KBTBD11 | c.1578A>T p.R526= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs1285791077; called by muse, mutect2, varscan2
- KCNA1 | c.1062G>A p.S354= | Silent (SNP) | VAF 129/221 reads (58%) | catalogued as rs779989266, COSV66838312; called by muse, mutect2, varscan2
- MCM7 | c.381T>A p.P127= | Silent (SNP) | VAF 195/421 reads (46%) | called by muse, mutect2, varscan2
- MVP | c.1053C>T p.H351= | Silent (SNP) | VAF 74/483 reads (15%) | catalogued as rs1321673852; called by muse, mutect2, varscan2
- PCDHB4 | c.924C>T p.F308= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV52021508; called by muse, varscan2
- PKD1 | c.1857G>A p.P619= | Silent (SNP) | VAF 59/109 reads (54%) | catalogued as rs749014917; called by muse, mutect2, varscan2
- POU2AF1 | c.372G>T p.V124= | Silent (SNP) | VAF 127/378 reads (34%) | called by muse, mutect2, varscan2
- RYR1 | c.2118C>T p.V706= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as rs769623563, COSV62103182; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAMD15 | c.1521C>T p.F507= | Silent (SNP) | VAF 56/142 reads (39%) | catalogued as rs143386437; called by muse, varscan2
- SRRM4 | c.504G>A p.R168= | Silent (SNP) | VAF 28/155 reads (18%) | called by muse, mutect2, varscan2
- SULF2 | c.768G>A p.P256= | Silent (SNP) | VAF 98/293 reads (33%) | catalogued as rs201684871, COSV100736945, COSV63414476; called by muse, mutect2, varscan2
- THSD4 | c.165G>T p.V55= | Silent (SNP) | VAF 29/38 reads (76%) | called by muse, mutect2, varscan2
- TSHR | c.1047C>T p.N349= | Silent (SNP) | VAF 198/591 reads (34%) | catalogued as rs370857348; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBE2O | c.3042C>T p.A1014= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs150733080; called by muse, mutect2, varscan2
- WDR36 | c.1011C>T p.A337= | Silent (SNP) | VAF 81/226 reads (36%) | called by muse, mutect2, varscan2
- CFAP46 | c.660+27C>T | Intron (SNP) | VAF 55/183 reads (30%) | catalogued as rs753676161; called by muse, mutect2, varscan2
- CORT | c.-62C>T | 5'UTR (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- KRT8P11 | n.545G>A | RNA (SNP) | VAF 79/249 reads (32%) | catalogued as rs762050968; called by muse, mutect2, varscan2
- MATR3 | c.*2144G>C | 3'UTR (SNP) | VAF 132/178 reads (74%) | called by muse, mutect2, varscan2
- PERM1 | chr1:981152 G>A | 5'Flank (SNP) | VAF 35/103 reads (34%) | catalogued as rs373197642; called by muse, mutect2, varscan2
- PKD1L2 | n.853G>A | RNA (SNP) | VAF 105/128 reads (82%) | catalogued as rs772490214; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1265+2223G>T | Intron (SNP) | VAF 67/141 reads (48%) | called by muse, mutect2, varscan2
- XIAP | c.*2820A>G | 3'UTR (SNP) | VAF 125/148 reads (84%) | catalogued as rs774722477; called by muse, varscan2
